CCDI case PBCNLD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/05d486c0-e1f9-420d-b895-d8d29d2b830a

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 0.9 years (318 days).

Biospecimens (3 samples)
- Sample 0DVZ0S: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DVZ13: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVZ1I: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
